CCDI case PBCVEK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a090ddb9-b0d2-467d-9ee9-01fa93e08dc9

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E0CSP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E0CT8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0CV5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
